Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A7U8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A7U8-06A (Metastatic).

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Small bowel, partial resection

- Segment of small bowel with metastatic neoplasm morphologically consistent

with metastatic melanoma, 6.5 cm in greatest dimension

- Tumor involves mesentery and extends into muscularis propria

- Margins appear viable and negative for tumor

- Tumor appears approximately 80% viable

ICD-O 3

Melanoma NOS 8720/3

Site: Small intestine NOS C17.9

QW 5/16/14

Clinical History:

Clinical diagnosis of melanoma.

Gross Description:

Specimen A is received in formalin appropriately labeled with "partial small

bowel resection" and is a 7.5 cm in length x 1.5 cm in diameter segment of small

bowel. A 6.5 x 4.1 x 2.2 cm mass is adherent to the serosa within the

mesentery. The mass is white/tan, nodular and bulging. The cut surface is

predominantly tan/white and gritty with focal areas of black pigment. The tumor

is 1.5 cm from the closest mucosal margin and 2.5 cm from the mesenteric margin.

The specimen is received with both ends of the small bowel shut with staples.

The serosa of the small bowel is pink/tan, smooth and glistening. Opening

reveals yellow/tan mucosa with normal folding. The cut surfaces reveal the

tumor abuts the serosal surface of the small bowel but does not invade into the muscle.

Block Summary:

A1-A2 - Mucosal margins unoriented, en face

A3 - Mesenteric margin, perpendicular

A4-A5 - Tumor with respect to the bowel wall

A6 - Tumor with respect to the mesentery

Tissue remains in formalin.

Donor/Specimen/Primary noted		
Review by (signature)		

Source: NCI Genomic Data Commons file d40623c9-3cfa-494b-b34c-a7151cf7e981 (TCGA-FR-A7U8.7AC59344-A5BD-4E6B-B47E-C6AC3BEED05E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).